Somatic mutation profile of tumor specimen 0DBZ5C from CCDI case PBBLMB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Schwannoma, NOS; Tissue or organ of origin: Spinal cord; Age at diagnosis: 14.3 years (5,213 days).
Specimen 0DBZ5C: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3980d14f-59b3-41a5-8c1b-21cacabaf87d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DBZ51 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ec23e929-4be9-4a50-a50f-0a8326d2bc77

The open-access MAF lists 9 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Intron 2, 3'UTR 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PPAN-P2RY11 | c.1162G>A p.E388K | Missense Mutation (SNP) | VAF 122/534 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.459); catalogued as rs937426336; called by muse, varscan2
- TRIO | c.9215G>A p.R3072Q | Missense Mutation (SNP) | VAF 72/1498 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs202157396; called by muse, mutect2
- ARHGAP35 | c.1870G>T p.D624Y | Missense Mutation (SNP) | VAF 28/590 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- OR51Q1 | c.89C>T p.S30F | Missense Mutation (SNP) | VAF 102/1342 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2
- PRPH2 | c.100A>T p.I34F | Missense Mutation (SNP) | VAF 58/738 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.251); called by muse, mutect2
- CRYL1 | c.567G>A p.E189= | Silent (SNP) | VAF 149/571 reads (26%) | catalogued as COSV53421048; called by muse, mutect2, varscan2
- DPM3 | c.-32+85G>C | Intron (SNP) | VAF 7/77 reads (9%) | called by muse, mutect2
- GH2 | c.457-35C>T | Intron (SNP) | VAF 151/743 reads (20%) | catalogued as rs1449312173; called by muse, mutect2, varscan2
- GRXCR2 | c.*60C>A | 3'UTR (SNP) | VAF 10/296 reads (3%) | called by muse, mutect2
